Somatic mutation profile of tumor specimen TCGA-27-1834-01A (aliquot TCGA-27-1834-01A-01W-0643-08) from TCGA case TCGA-27-1834, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 56.3 years (20,568 days).
Specimen TCGA-27-1834-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8980a5ae-29b9-4850-ac1b-c918c0bb5dbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-1834-10A (Blood Derived Normal), aliquot TCGA-27-1834-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0480797d-1ce6-46e4-8f27-b24c9597a052

The open-access MAF lists 107 somatic variants for this specimen: 70 protein-altering or splice-affecting, 35 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 35, Frame Shift Ins 6, Nonsense Mutation 3, In Frame Del 1, RNA 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC4 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs765741241; called by muse, mutect2, varscan2
- ANKS4B | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs754271798, COSV61139377; called by muse, mutect2, varscan2
- ARHGEF4 | c.1921G>T p.A641S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.041); catalogued as rs1558906436; called by muse, mutect2
- ARHGEF40 | c.2209dup p.A737Gfs*94 | Frame Shift Ins (INS) | VAF 13/104 reads (13%) | catalogued as rs749402223; called by mutect2, varscan2
- ARID1A | c.3187G>A p.G1063R | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61375870; called by muse, mutect2, varscan2
- ATP10A | c.1358C>A p.A453E | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV63522082; called by muse, mutect2
- C9orf116 | c.326C>T p.T109I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65646517; called by muse, mutect2, varscan2
- CARF | c.1861T>C p.C621R | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV57548065; called by muse, mutect2, varscan2
- CDH24 | c.714dup p.L239Afs*67 | Frame Shift Ins (INS) | VAF 8/62 reads (13%) | catalogued as rs765496989; called by mutect2, varscan2
- CELSR3 | c.2675G>A p.R892H | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771709882, COSV50884054; called by muse, mutect2, varscan2
- CP | c.1339G>A p.G447S | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52834522; called by muse, varscan2
- CRNN | c.709G>T p.G237C | Missense Mutation (SNP) | VAF 176/348 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55122429; called by muse, mutect2, varscan2
- CYP11B2 | c.965C>T p.P322L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV59995910, COSV59996388; called by muse, mutect2, varscan2
- CYP2A13 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs143140637; called by muse, mutect2
- DDR1 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs762082578, COSV61321876; called by muse, mutect2, varscan2
- DENND2C | c.1904C>T p.A635V (on ENST00000393274 / NM_001256404.2; = p.A578V on NM_198459.4) | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67922158; called by muse, mutect2, varscan2
- ENPEP | c.2525C>T p.T842M | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs200338472, COSV54451167; called by muse, mutect2, varscan2
- EPHA4 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.523); catalogued as rs748076314, COSV56035910; called by muse, mutect2, varscan2
- FAM107B | c.139C>G p.P47A (on ENST00000378458 / NM_001320737.1; = p.P222A on NM_031453.3) | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV51686511, COSV51693713; called by muse, mutect2, varscan2
- FLG | c.10538C>T p.A3513V | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs143278829, COSV64243057; called by muse, mutect2, varscan2
- GPD2 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV60093463; called by muse, mutect2, varscan2
- GSAP | c.1235C>A p.S412Y | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57529128; called by muse, mutect2
- IFNB1 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 114/158 reads (72%) | SIFT tolerated (0.3); PolyPhen benign (0.403); catalogued as COSV66525132, COSV66525281; called by muse, mutect2, varscan2
- LHCGR | c.215T>A p.L72H | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54298394; called by muse, mutect2, varscan2
- MBNL1 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56830230, COSV56833536; called by muse, mutect2, varscan2
- MVK | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 316/395 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV57332135; called by muse, mutect2, varscan2
- NELL1 | c.1402C>T p.R468C | Missense Mutation (SNP) | VAF 165/326 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs371025282; called by muse, mutect2, varscan2
- NR3C2 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV60992886; called by muse, mutect2, varscan2
- OPCML | c.280A>T p.T94S | Missense Mutation (SNP) | VAF 98/327 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.145); catalogued as COSV59429281; called by muse, mutect2, varscan2
- OR1J4 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 184/249 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV61589937; called by muse, varscan2
- OR5M8 | c.692A>T p.E231V | Missense Mutation (SNP) | VAF 49/81 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV59117130; called by muse, mutect2, varscan2
- OR6B1 | c.616A>G p.I206V | Missense Mutation (SNP) | VAF 71/508 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1465345184, COSV68770270; called by muse, mutect2, varscan2
- PHLDB2 | c.1142G>A p.R381K | Missense Mutation (SNP) | VAF 39/802 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.437); catalogued as rs1209433982, COSV67312460; called by muse, mutect2
- REEP5 | c.213-1G>T p.X71_splice | Splice Site (SNP) | VAF 9/106 reads (8%) | catalogued as COSV54840465; called by muse, mutect2
- SLC2A5 | c.1114A>T p.M372L | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs1413528090; called by muse, mutect2, varscan2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 38/264 reads (14%) | catalogued as rs763321097; called by mutect2, varscan2
- TFAP2B | c.1111C>A p.L371M | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.132); catalogued as COSV99036340; called by muse, mutect2
- TRIM42 | c.606G>T p.K202N | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV53880392; called by muse, mutect2
- TTN | c.139T>A p.S47T | Missense Mutation (SNP) | VAF 26/57 reads (46%) | PolyPhen benign (0); catalogued as COSV59886738, COSV60027269; called by muse, varscan2
- TTYH1 | c.225dup p.E76Rfs*39 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | catalogued as rs765795892; called by pindel, varscan2
- AAAS | c.1489G>T p.V497L | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ACAA1 | c.584C>A p.S195* | Nonsense Mutation (SNP) | VAF 82/704 reads (12%) | called by muse, mutect2, varscan2
- ACCS | c.1439G>A p.G480D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- BCCIP | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.038); called by muse, mutect2
- C7orf31 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 18/203 reads (9%) | called by muse, mutect2
- CARD11 | c.2714G>T p.R905M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- CD33 | c.998A>G p.E333G | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- CENPE | c.6293C>T p.S2098F | Missense Mutation (SNP) | VAF 34/249 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUL4A | c.1185G>T p.E395D (on ENST00000375440 / NM_001008895.4; = p.E295D on NM_003589.3) | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DNAJB13 | c.381dup p.L128Afs*33 | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- FANCD2OS | c.426G>T p.E142D | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.866); called by muse, mutect2
- FLG | c.8706_8732del p.E2902_A2911delinsD | In Frame Del (DEL) | VAF 34/412 reads (8%) | called by mutect2, pindel
- IGSF10 | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 40/1305 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2
- KAT8 | c.1344dup p.K449Qfs*39 | Frame Shift Ins (INS) | VAF 5/34 reads (15%) | called by mutect2, varscan2
- KCNMB3 | c.312C>A p.D104E | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- KRT20 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 38/528 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- LAMP5 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NCOA3 | c.4121G>A p.S1374N (on ENST00000371998 / NM_181659.3; = p.S1370N on NM_006534.4) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NEMP1 | c.1317G>T p.Q439H (on ENST00000300128 / NM_001130963.2; = p.Q366H on NM_015257.3) | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.332); called by muse, mutect2
- OTOA | c.1916C>T p.A639V (on ENST00000286149; = p.A625V on NM_144672.4) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.67); PolyPhen benign (0.021); called by muse, mutect2
- PDYN | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.036); called by muse, mutect2
- RPS6KB1 | c.1405C>T p.Q469* | Nonsense Mutation (SNP) | VAF 40/139 reads (29%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.120C>A p.D40E (on ENST00000265814 / NM_001198628.1; = p.D13E on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/488 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.72); called by muse, mutect2
- SEC14L3 | c.281A>C p.D94A | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.193); called by mutect2, varscan2
- STRAP | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.29); called by muse, mutect2
- TRIM33 | c.3262C>A p.P1088T | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.281); called by muse, mutect2
- USP2 | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.087); called by muse, mutect2
- VPS45 | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 39/296 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- XIRP1 | c.1607G>A p.G536D | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF567 | c.208G>T p.G70C (on ENST00000536254 / NM_001322913.1; = p.G39C on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.52); called by muse, mutect2
- ADCY2 | c.2709C>T p.S903= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs774455530, COSV57862905; called by muse, mutect2, varscan2
- AHNAK | c.9987A>C p.I3329= | Silent (SNP) | VAF 4/26 reads (15%) | called by mutect2, varscan2
- ANK1 | c.4716C>A p.G1572= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV55876050; called by muse, mutect2
- APOA2 | c.42C>T p.C14= | Silent (SNP) | VAF 14/173 reads (8%) | called by muse, mutect2
- CCDC130 | c.279C>A p.L93= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs1406738160; called by muse, mutect2, varscan2
- CCDC87 | c.651C>T p.F217= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs17853294, COSV59578208; called by muse, mutect2, varscan2
- CDCP1 | c.1341C>A p.S447= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2, varscan2
- CFAP65 | c.3204C>T p.P1068= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1457035447; called by muse, mutect2, varscan2
- CLCN1 | c.2265G>A p.P755= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs761474906, COSV58368300; called by muse, mutect2
- CSF2RA | c.357C>T p.T119= | Silent (SNP) | VAF 240/1200 reads (20%) | catalogued as COSV100817887, COSV62625112; called by muse, mutect2, varscan2
- CSTF1 | c.1242G>A p.T414= | Silent (SNP) | VAF 211/469 reads (45%) | catalogued as rs748667806, COSV53859070; called by muse, mutect2, varscan2
- DOCK8 | c.4335C>T p.I1445= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- EPHB1 | c.2166G>T p.V722= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV67663261; called by muse, mutect2, varscan2
- FER1L6 | c.948C>A p.P316= | Silent (SNP) | VAF 24/866 reads (3%) | called by muse, mutect2
- FOXA1 | c.1320C>T p.G440= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as rs752035534, COSV51646667; called by muse, mutect2
- GARRE1 | c.2127A>T p.T709= | Silent (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
- GOLGB1 | c.963G>T p.L321= | Silent (SNP) | VAF 39/242 reads (16%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.1965G>A p.V655= | Silent (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- KCNC4 | c.1464G>T p.L488= | Silent (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- KCTD2 | c.216C>A p.R72= | Silent (SNP) | VAF 17/26 reads (65%) | called by muse, varscan2
- KLHL8 | c.558C>T p.D186= | Silent (SNP) | VAF 23/259 reads (9%) | catalogued as rs764730839; called by muse, mutect2
- MBD1 | c.1735C>T p.L579= (on ENST00000269468 / NM_001323950.1; = p.L477= on NM_002384.2) | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1005161632, COSV99496629; called by muse, varscan2
- MS4A4A | c.678C>T p.H226= | Silent (SNP) | VAF 56/99 reads (57%) | catalogued as COSV59701659; called by muse, mutect2, varscan2
- MTOR | c.5556G>A p.E1852= | Silent (SNP) | VAF 89/189 reads (47%) | called by muse, mutect2, varscan2
- NPC1L1 | c.4029A>G p.K1343= | Silent (SNP) | VAF 10/334 reads (3%) | called by muse, mutect2
- OGFOD1 | c.1224C>T p.N408= | Silent (SNP) | VAF 13/193 reads (7%) | called by muse, mutect2
- OLFM4 | c.1182T>A p.V394= | Silent (SNP) | VAF 141/193 reads (73%) | catalogued as COSV54578127; called by muse, mutect2, varscan2
- OR10G2 | c.294G>A p.P98= | Silent (SNP) | VAF 42/71 reads (59%) | catalogued as rs749275776, COSV73390396; called by muse, mutect2, varscan2
- PPM1G | c.246G>A p.Q82= | Silent (SNP) | VAF 21/72 reads (29%) | called by muse, varscan2
- SLC39A11 | c.912C>T p.Y304= (on ENST00000542342 / NM_001159770.2; = p.Y297= on NM_139177.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as rs146713017; called by muse, varscan2
- SLC39A8 | c.927C>A p.L309= | Silent (SNP) | VAF 40/239 reads (17%) | called by muse, mutect2, varscan2
- SMAD3 | c.102G>A p.A34= | Silent (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- SOX30 | c.594C>T p.G198= | Silent (SNP) | VAF 36/53 reads (68%) | catalogued as COSV53937931; called by muse, mutect2, varscan2
- VWA8 | c.5397C>T p.C1799= | Silent (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- XIRP2 | c.618C>T p.D206= (on ENST00000628543; = p.D381= on NM_152381.6) | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV54680205, COSV54708203; called by muse, mutect2
- DCHS2 | n.580C>T | RNA (SNP) | VAF 74/709 reads (10%) | called by muse, mutect2, varscan2
- DST | c.4297-4120T>C | Intron (SNP) | VAF 8/194 reads (4%) | catalogued as COSV99753196; called by muse, mutect2
